Gene-level copy-number profile of tumor specimen C3L-04732-02 from CPTAC case C3L-04732, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 83.1 years (30,365 days).
Specimen C3L-04732-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1a69e3bf-78b6-4edc-bf69-937ef0ad8460.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04732-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/5b48cbae-8c5e-4925-84f0-28e2148b1609

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 527; copy number 1: 9,292; copy number 2: 46,189; copy number 3: 1,012; copy number 4: 1,874; copy number 5: 12.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,201,647–87,357,882, 5 genes (within-gene range 0–1): NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863.
- chr10:87,863,625–88,584,530, 7 genes (within-gene range 0–1): PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.
- chr21:9,053,122–9,059,060, 1 gene: CR392039.4.
- chr21:9,325,013–9,368,775, 2 genes (within-gene range 0–1): CR381653.1, SNX18P12.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:63,263,065–63,368,156, 10 genes, copy number 5: AC006455.7, ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P.
- chr7:133,082,829–133,170,514, 2 genes, copy number 5: RNU6-92P, ST13P7.

Autosomal genes at a single copy (total copy number 1): 6,948. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
